Somatic mutation profile of tumor specimen TCGA-NJ-A55A-01A (aliquot TCGA-NJ-A55A-01A-11D-A25L-08) from TCGA case TCGA-NJ-A55A, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.7 years (28,022 days).
Specimen TCGA-NJ-A55A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f56fcde9-5212-46d4-bd4f-73250c450673.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A55A-10A (Blood Derived Normal), aliquot TCGA-NJ-A55A-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c8f7d14-91f9-4109-abc5-221211eef2f1

The open-access MAF lists 106 somatic variants for this specimen: 78 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 24, RNA 2, Nonstop Mutation 1, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACA | c.2476A>G p.M826V | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1255779101; called by muse, mutect2
- ADAM29 | c.218T>G p.L73W | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100822220; called by muse, mutect2, varscan2
- ATP10B | c.3013G>T p.A1005S | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV100515655; called by muse, mutect2
- ATP7A | c.3782C>G p.A1261G | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100431560; called by muse, mutect2
- BTG1 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV99755724; called by muse, mutect2
- C16orf46 | c.546G>T p.R182S | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as COSV100215452, COSV55150490; called by muse, mutect2
- CAPRIN2 | c.1337C>A p.T446N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99195644; called by muse, mutect2
- CDH7 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100543117; called by muse, mutect2
- CEP164 | c.3907C>A p.P1303T | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99634210; called by muse, mutect2
- CLCN5 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 10/307 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as CM139684; called by muse, mutect2
- CNTNAP2 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62189143; called by muse, mutect2
- CPA6 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99912525, COSV99913798; called by muse, mutect2, varscan2
- CUL4B | c.1910G>A p.C637Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100341102; called by muse, mutect2
- DLL3 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV99219419; called by muse, mutect2
- DSG3 | c.284C>A p.P95Q | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104377339, COSV99934653; called by muse, mutect2
- ECD | c.710T>A p.L237Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100881496; called by muse, mutect2, varscan2
- FAM47B | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.69); catalogued as COSV100264572, COSV61453102; called by muse, mutect2
- FGD5 | c.3038G>T p.R1013L | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as COSV99549101; called by muse, mutect2
- FLG | c.5222G>T p.G1741V | Missense Mutation (SNP) | VAF 16/351 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100912048; called by muse, mutect2
- GJB6 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs761985641, COSV53833850; called by muse, mutect2
- GPC1 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99883158; called by muse, mutect2
- GPR148 | c.153G>T p.W51C | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99998584, COSV99998709; called by muse, mutect2
- GRM5 | c.2531G>T p.R844L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV59614581; called by muse, mutect2
- HCLS1 | c.822G>T p.R274S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100101069, COSV57522498; called by muse, mutect2, varscan2
- JAKMIP2 | c.2418C>A p.N806K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as COSV99509114; called by muse, mutect2
- KCND2 | c.1040A>T p.K347M | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100478196; called by muse, mutect2, varscan2
- KCNT2 | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99653511; called by muse, mutect2, varscan2
- KMT2A | c.6078G>C p.M2026I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.437); catalogued as COSV100629699; called by muse, mutect2
- LRP1B | c.12620G>A p.C4207Y | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101260115; called by muse, mutect2
- LY6E | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as COSV99465176; called by muse, mutect2
- LYPD3 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99747222; called by muse, mutect2, varscan2
- MED17 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99316210; called by muse, mutect2, varscan2
- MEX3B | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100314199; called by muse, mutect2
- MPPED2 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100813523; called by muse, mutect2, varscan2
- MS4A6E | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.91); catalogued as COSV100279223; called by muse, mutect2
- NLRP7 | c.1786A>T p.I596F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV100053253; called by muse, mutect2
- OGT | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as COSV101035594; called by muse, mutect2
- OR10K2 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV100149527, COSV100149638; called by muse, mutect2
- OR4S2 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412775; called by muse, mutect2, varscan2
- OR6K6 | c.348G>T p.E116D (on ENST00000368144; = p.E92D on NM_001005184.1) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100933781; called by muse, mutect2, varscan2
- PCDHGA3 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV99545729; called by muse, mutect2
- PCDHGA7 | c.2378C>T p.T793I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99545733; called by muse, mutect2
- PKHD1 | c.1321A>T p.T441S | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100584379; called by muse, mutect2, varscan2
- PKP2 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as COSV99298399; called by muse, mutect2
- POLE | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs1307922680, COSV100268006; ClinVar: uncertain significance; called by muse, mutect2
- POU6F1 | c.1254G>T p.K418N | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.607); catalogued as COSV100374795; called by muse, mutect2
- PRR11 | c.994G>C p.A332P | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51877072, COSV99231792; called by muse, mutect2
- PRSS38 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV100816556; called by muse, mutect2, varscan2
- PTPRN | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.3); catalogued as COSV99834274; called by muse, mutect2
- RYR1 | c.6346C>A p.L2116M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100616802; called by muse, mutect2, varscan2
- RYR2 | c.4756C>A p.L1586I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV100772525; called by muse, mutect2, varscan2
- SAGE1 | c.968T>C p.I323T | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs782261322, COSV100187806; called by muse, mutect2, varscan2
- SATB2 | c.1654A>G p.R552G | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53484848, COSV99612445; called by muse, mutect2
- SCML2 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319102, COSV99319447; called by muse, mutect2
- SERPINB12 | c.1076C>A p.A359E | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99501510; called by muse, mutect2
- SETX | c.2120T>G p.I707R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.216); catalogued as COSV99810744; called by muse, mutect2
- SGCZ | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV101171480, COSV66015978; called by muse, mutect2
- SLC16A14 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99039479, COSV99725854; called by muse, mutect2, varscan2
- SNX25 | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV99253379; called by muse, mutect2
- SPATA31A6 | c.2074G>T p.V692L | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs1236070972; called by muse, mutect2
- SSX2IP | c.1844A>G p.*615Wext*25 | Nonstop Mutation (SNP) | VAF 11/125 reads (9%) | catalogued as COSV100642710; called by muse, mutect2
- SYT10 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV99951917; called by muse, mutect2
- TAPBP | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1442648013, COSV101418750; called by muse, mutect2
- TAS2R38 | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as COSV101516529; called by muse, mutect2
- TRIM39 | c.23A>T p.E8V | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as COSV100935905; called by muse, mutect2
- TSPOAP1 | c.4664G>T p.W1555L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52106019; called by muse, mutect2, varscan2
- TTN | c.20686A>C p.N6896H (on ENST00000591111; = p.N5969H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV100627121; called by mutect2, varscan2
- UNC5D | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99778359; called by muse, mutect2, varscan2
- UNC79 | c.6400G>T p.G2134C (on ENST00000393151 / NM_001346218.2; = p.G1957C on NM_020818.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99829666; called by muse, mutect2
- Z83844.2 | c.1608C>G p.S536R | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV99312936; called by muse, mutect2
- ZER1 | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.085); catalogued as COSV52567931, COSV99402380; called by mutect2, varscan2
- ZNF142 | c.5020C>T p.H1674Y (on ENST00000411696 / NM_001379660.1; = p.H1474Y on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV101346954; called by muse, mutect2
- ZNF34 | c.974A>T p.H325L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100603386, COSV58641143; called by muse, mutect2, varscan2
- ZNF407 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV99996588; called by muse, mutect2
- ZNF70 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100558939; called by muse, mutect2
- JAKMIP2 | c.1936del p.R646Efs*8 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- LONRF1 | c.1364dup p.N455Kfs*2 | Frame Shift Ins (INS) | VAF 10/94 reads (11%) | called by mutect2, pindel, varscan2
- PDE10A | c.1737C>A p.D579E | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.028); called by muse, mutect2
- ADAM23 | c.1275G>C p.V425= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as COSV100008639; called by muse, mutect2
- AJAP1 | c.855C>A p.T285= | Silent (SNP) | VAF 9/189 reads (5%) | catalogued as COSV100981997; called by muse, mutect2
- AMPH | c.369C>A p.T123= | Silent (SNP) | VAF 21/211 reads (10%) | catalogued as COSV100343412; called by muse, mutect2, varscan2
- CERCAM | c.954G>T p.G318= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1296354394, COSV100864102; called by muse, mutect2
- CUL9 | c.5514G>A p.G1838= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99335932; called by muse, mutect2, varscan2
- DYTN | c.1521G>C p.V507= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV101510898, COSV71751709; called by muse, mutect2
- FPR1 | c.354C>T p.L118= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs757978120, COSV100494202; called by muse, mutect2
- H2AW | c.354C>A p.P118= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV100797315; called by muse, mutect2
- KBTBD6 | c.336G>T p.V112= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV101068853, COSV65271143; called by muse, mutect2
- KCNA5 | c.1656C>A p.V552= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV52906437, COSV99364155; called by muse, mutect2, varscan2
- KIF3C | c.2298T>C p.S766= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV99267856; called by muse, mutect2
- MAP1B | c.3354C>T p.G1118= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99702883; called by muse, mutect2, varscan2
- MAP1LC3C | c.216C>A p.I72= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100606545; called by muse, mutect2, varscan2
- MFSD6L | c.1455C>A p.P485= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100319871; called by muse, mutect2
- OR6K3 | c.465G>T p.R155= (on ENST00000368146; = p.R139= on NM_001005327.2) | Silent (SNP) | VAF 6/109 reads (6%) | catalogued as COSV100933881; called by muse, mutect2
- PCNT | c.8118G>C p.V2706= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100855986; called by muse, mutect2, varscan2
- POLQ | c.3813A>T p.S1271= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as rs1330477759, COSV99952839; called by muse, mutect2
- PVR | c.856C>T p.L286= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99495966; called by muse, mutect2, varscan2
- S100G | c.171G>A p.L57= | Silent (SNP) | VAF 5/115 reads (4%) | catalogued as COSV100827011; called by muse, mutect2
- SLC4A8 | c.3003G>C p.L1001= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV100177443; called by muse, mutect2
- TAAR8 | c.393T>A p.I131= | Silent (SNP) | VAF 17/311 reads (5%) | called by muse, mutect2
- TAS2R60 | c.129C>A p.G43= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as rs140806474, COSV100223663; called by muse, mutect2, varscan2
- WASHC4 | c.429C>T p.F143= | Silent (SNP) | VAF 6/107 reads (6%) | catalogued as COSV100162733; called by muse, mutect2
- ZAN | c.1758C>A p.V586= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV61807635; called by muse, mutect2, varscan2
- AC073310.1 | n.295T>A | RNA (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2
- AC073310.1 | n.296G>T | RNA (SNP) | VAF 20/199 reads (10%) | catalogued as rs1262197769; called by muse, mutect2
- PLCE1 | c.1207-42845A>T | Intron (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99596858; called by muse, mutect2
- WT1 | chr11:32438951 G>T | 5'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
